Somatic mutation profile of tumor specimen TCGA-EL-A4K9-01A (aliquot TCGA-EL-A4K9-01A-11D-A257-08) from TCGA case TCGA-EL-A4K9, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 68.4 years (24,980 days).
Specimen TCGA-EL-A4K9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fb7badf-e00c-4f66-ba29-4cfc170c0d63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A4K9-11A (Solid Tissue Normal), aliquot TCGA-EL-A4K9-11A-11D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a63560e-908b-467f-88ee-0980a44e0bc8

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, Nonsense Mutation 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AMPD2 | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as COSV99857458; called by muse, mutect2, varscan2
- CENPF | c.5639A>G p.E1880G | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV100871550; called by muse, mutect2, varscan2
- DDX23 | c.1291A>G p.I431V | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.309); catalogued as COSV100339675; called by muse, mutect2, varscan2
- GOT1 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs752608223, COSV100981672; called by muse, mutect2, varscan2
- HSPG2 | c.3167T>C p.I1056T | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776352688, COSV101020472; called by muse, mutect2, varscan2
- ITPR2 | c.4509G>A p.Q1503= | Splice Region (SNP) | VAF 26/79 reads (33%) | catalogued as rs1173998553, COSV101189867; called by muse, mutect2, varscan2
- SCN8A | c.4517G>A p.R1506H | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs760096460, COSV61985354; ClinVar: likely benign; called by muse, mutect2
- SECISBP2 | c.1267G>C p.E423Q | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV100368568; called by muse, mutect2, varscan2
- ZNF660 | c.17G>C p.R6T | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100502656; called by muse, mutect2, varscan2
- ZNF660 | c.106G>C p.D36H | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV100502658; called by muse, mutect2, varscan2
- TMPRSS15 | c.682del p.R228Dfs*4 | Frame Shift Del (DEL) | VAF 30/108 reads (28%) | called by mutect2, pindel, varscan2
- EPHB6 | c.591C>G p.V197= | Silent (SNP) | VAF 126/374 reads (34%) | catalogued as rs1393997408, COSV101235951; called by muse, varscan2
- RPUSD4 | c.150C>G p.L50= | Silent (SNP) | VAF 17/344 reads (5%) | catalogued as COSV100028622; called by muse, mutect2
- TFAP2B | c.360T>C p.S120= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs886061564, COSV99539737; ClinVar: uncertain significance; called by muse, mutect2, varscan2
